Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VI, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VI-01A (Primary Tumor).

[page 1 of 2]
Neck
and Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Left thyroid nodule FNA papillary thyroid cancer.

Specimens Submitted:

1: Left para-tracheal lymph node, thyroid gland and central compartment lymph nodes

DIAGNOSIS:

1. Left para-tracheal lymph node, thyroid gland and central compartment lymph nodes:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.2 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic foci present

Papillary microcarcinomas: right lobe, one focus (0.2 cm in greatest dimension); left lobe, two foci (0.1 cm and 0.2 cm in greatest dimension, respectively)

Adenoma(s) (away from the carcinoma):

ICD-O3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5-2-12
120

[page 2 of 2]
Not Identified
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis
Parathyroid Glands:
Identified
One, intrathyroidal parathyroid (left lobe)

Lymph Nodes:

Metastatic papillary carcinoma to 3 of 5 lymph nodes (3/5); Largest involved lymph node measures 0.8 cm in greatest dimension; Largest metastatic tumor deposit measures 0.6 cm in greatest dimension; No extracapsular extension

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "left paratracheal lymph node, thyroid gland and central compartment lymph nodes" and consists of a thyroid weighing 11 g. The right lobe measures 3.5 x 2.5 x 1 cm, the left lobe measures 4 x 2 x 1.5 cm, the isthmus measures 1 x 0.5 x 0.5 cm, and a pyramidal lobe measures 2 x 0.5 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 1.2 cm tan nodule with central papillary excrescences in the inferior left lobe. Sections through the remaining tissue reveal multiple bilateral colloid nodules. The remaining thyroid parenchyma is red tan and beefy. There are multiple lymph nodes identified including a grossly positive node attached to the inferior pole. Representative sections of the specimen are submitted for The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

NL - nodule left lobe
RL - right lobe
LL - left lobe
IS - isthmus
PL - pyramidal lobe
PLN- lymph nodes adjacent to pyramidal lobe
ILN- lymph node attached to inferior pole, bisected

Summary of Sections:

Part 1: Left para-tracheal lymph node, thyroid gland and central compartment lymph nodes

Block	Sect. Site	PCs
1	ILN	1
1	IS	1
3	LL	3
4	NL	4
1	PL	1
1	PLN	1
6	RL	6

Source: NCI Genomic Data Commons file 0f176c5f-6440-440b-857d-e01b591d5c2d (TCGA-DJ-A3VI.0301C712-DB98-44EA-9BEA-51F22749E0B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).